HCMI case HCM-CSHL-0080-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b348a82-127f-42ac-bc41-c55fdf8cac7a

Demographics
Sex at birth: female; Year of birth: 1956.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 60.9 years (22,238 days); AJCC staging edition: 8th; AJCC pathologic T: T1c; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 4 or More; Peripancreatic lymph nodes tested: 87.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -22 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 43 days; Days to treatment end: 200 days.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 233 days; Days to treatment end: 272 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 298, day 440.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 51 kg; Height: 160 cm; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Occasional Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0080-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0080-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 46; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 53; Percent lymphocyte infiltration: 45; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0080-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 31; Percent tumor nuclei: 45; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 67; Percent lymphocyte infiltration: 46; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0080-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0080-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
